Somatic mutation profile of tumor specimen TCGA-B2-3923-01A (aliquot TCGA-B2-3923-01A-02D-1386-10) from TCGA case TCGA-B2-3923, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.7 years (21,793 days).
Specimen TCGA-B2-3923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d675f3f-c6d7-459a-a719-73e5493ca596.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-3923-10A (Blood Derived Normal), aliquot TCGA-B2-3923-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5444db7b-45e4-4902-adf9-4cdb6efc772d

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.356); catalogued as COSV65560659; called by muse, mutect2, varscan2
- AHSA1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV53631343, COSV53632886; called by muse, mutect2
- CYP2S1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs765253772, COSV100027424; called by muse, varscan2
- DCAF12L2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1338664181, COSV63580237, COSV63583223; called by muse, mutect2, varscan2
- DOP1B | c.6083T>C p.M2028T | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs996130220, COSV67692664; called by muse, mutect2
- FERMT1 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV54091896; called by muse, mutect2
- GAN | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 71/204 reads (35%) | catalogued as COSV73720808; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 49/366 reads (13%) | catalogued as rs548474277; called by mutect2, varscan2
- NGLY1 | c.1672G>T p.G558W | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV54985128; called by muse, mutect2, varscan2
- NUP62CL | c.336T>G p.N112K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65235559; called by muse, mutect2, varscan2
- PJA2 | c.1539T>G p.S513R | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63272221; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as rs781830688; called by mutect2, varscan2
- TRPM4 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759027293, COSV53261327, COSV53264648; called by muse, mutect2, varscan2
- USP15 | c.441_443del p.V148del | In Frame Del (DEL) | VAF 65/222 reads (29%) | catalogued as rs1397041029; called by pindel, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | catalogued as rs746919573; called by mutect2, varscan2
- SLC24A2 | c.1668_1670del p.R557del | In Frame Del (DEL) | VAF 23/209 reads (11%) | called by mutect2, pindel
- ZNF292 | c.4417T>C p.S1473P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- C3orf20 | c.681C>T p.Y227= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV53783635; called by muse, mutect2, varscan2
- HYAL4 | c.1185C>T p.P395= | Silent (SNP) | VAF 73/170 reads (43%) | catalogued as COSV56137995; called by muse, mutect2, varscan2
- OXER1 | c.981C>T p.C327= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- SMARCA5 | c.1365A>G p.K455= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as COSV51643094; called by muse, mutect2
